Somatic mutation profile of tumor specimen TCGA-XF-AAMX-01A (aliquot TCGA-XF-AAMX-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 87.3 years (31,884 days).
Specimen TCGA-XF-AAMX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 394df8b9-dca6-49e4-8628-949ee41a307d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMX-10A (Blood Derived Normal), aliquot TCGA-XF-AAMX-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3890f844-f4e2-4d00-8dda-d086a617be63

The open-access MAF lists 374 somatic variants for this specimen: 283 protein-altering or splice-affecting, 82 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 242, Silent 82, Nonsense Mutation 18, Splice Site 8, Frame Shift Del 7, Intron 4, Splice Region 3, Frame Shift Ins 2, 5'UTR 2, RNA 2, In Frame Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5191G>T p.E1731* | Nonsense Mutation (SNP) | VAF 14/17 reads (82%) | catalogued as rs397507244, COSV100523074, COSV99070442; ClinVar: pathogenic / not provided; called by muse, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 85/103 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561dup p.R521Pfs*15 | Frame Shift Ins (INS) | VAF 6/11 reads (55%) | catalogued as rs767319284; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 25/30 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.2540C>G p.S847C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV60691260; called by muse, mutect2, varscan2
- ACD | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 20/33 reads (61%) | catalogued as rs1388018384, COSV99537289; called by muse, mutect2, varscan2
- ADAM29 | c.2453C>T p.T818M | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as rs201528348, COSV63666360; called by muse, mutect2, varscan2
- ADD3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53324791; called by muse, mutect2, varscan2
- ADGRA3 | c.3799A>T p.R1267W | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV51566562; called by muse, mutect2, varscan2
- ADGRB3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65411515; called by muse, mutect2, varscan2
- ADGRV1 | c.11698G>C p.E3900Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV67985801, COSV67991956; called by mutect2, varscan2
- ALKBH5 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.211); catalogued as COSV67687236; called by muse, mutect2, varscan2
- ALMS1 | c.7099G>C p.E2367Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52517627; called by muse, mutect2, varscan2
- ALMS1 | c.7252G>A p.D2418N | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52517635; called by muse, mutect2, varscan2
- ANAPC2 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV60571613; called by muse, mutect2, varscan2
- ANAPC2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1307911570, COSV100118800; called by muse, mutect2, varscan2
- ANAPC2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs772416110, COSV58808588; called by muse, mutect2, varscan2
- ANK3 | c.6347C>T p.S2116F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV55073442; called by muse, mutect2, varscan2
- ANK3 | c.5773G>C p.E1925Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); catalogued as COSV55073449; called by muse, mutect2, varscan2
- ANKRD35 | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as COSV62909586, COSV62911202; called by muse, mutect2, varscan2
- APOA2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1268122983, COSV57155622, COSV99248250; called by muse, mutect2
- APOB | c.10726C>A p.L3576I | Missense Mutation (SNP) | VAF 62/73 reads (85%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs763174107, COSV51946144; called by muse, mutect2, varscan2
- ARHGAP19 | c.1303C>A p.Q435K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1185464916, COSV57394893; called by muse, varscan2
- ARHGAP29 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.827); catalogued as rs748490963, COSV53115164; called by mutect2, varscan2
- ARID1B | c.2838C>T p.S946= | Splice Region (SNP) | VAF 4/9 reads (44%) | catalogued as CD1310782, COSV99266430; called by muse, mutect2, varscan2
- ASAP1 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs761366499, COSV63050964; called by muse, mutect2, varscan2
- ASL | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59189062; called by muse, mutect2, varscan2
- ASPHD1 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534872319, COSV58101945; called by muse, mutect2, varscan2
- ASXL2 | c.3121G>T p.A1041S | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs771257056, COSV55464507; called by muse, mutect2, varscan2
- ATP11C | c.3055C>T p.R1019* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV59575098; called by muse, mutect2, varscan2
- ATP1A1 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55193298; called by muse, mutect2, varscan2
- ATP1A2 | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768001, COSV63405167; called by muse, mutect2, varscan2
- ATR | c.7370A>C p.Y2457S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63389794; called by muse, mutect2, varscan2
- AVPR1A | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54547604; called by muse, mutect2, varscan2
- AZIN1 | c.727T>A p.F243I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61480940; called by muse, mutect2, varscan2
- BAIAP2 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV58335231, COSV58338802; called by muse, mutect2, varscan2
- BCAS3 | c.1087+2T>A p.X363_splice | Splice Site (SNP) | VAF 18/192 reads (9%) | catalogued as COSV101174744; called by muse, mutect2
- BCO2 | c.939A>C p.K313N | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.236); catalogued as COSV63064372; called by muse, mutect2, varscan2
- BICC1 | c.380A>T p.D127V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65863255; called by muse, mutect2, varscan2
- BIRC7 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV53902663; called by muse, mutect2, varscan2
- BRCA1 | c.5067G>A p.M1689I | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV58796123; called by muse, mutect2, varscan2
- BRCA1 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 89/96 reads (93%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as CM021508, COSV58796148; called by muse, varscan2
- C1QA | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1052031423, COSV65889943; called by muse, mutect2, varscan2
- C2orf78 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV68518725; called by muse, mutect2, varscan2
- C9orf131 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV56613003; called by muse, mutect2, varscan2
- CACNA2D1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs370389203; called by muse, mutect2, varscan2
- CALHM1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs201805642; called by muse, mutect2, varscan2
- CALU | c.89A>C p.H30P | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV50822728; called by muse, mutect2, varscan2
- CAMTA1 | c.4855A>T p.T1619S | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV57918491; called by muse, mutect2, varscan2
- CARMIL2 | c.1910C>G p.S637W | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100575894; called by muse, mutect2, varscan2
- CARMIL2 | c.3265C>G p.P1089A | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV104375130, COSV99537282; called by muse, varscan2
- CCDC88A | c.1178A>T p.D393V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55067261; called by muse, mutect2, varscan2
- CCL7 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99565423, COSV99565543; called by muse, mutect2, varscan2
- CCT8L2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV63463368; called by muse, mutect2, varscan2
- CELSR2 | c.5692G>T p.D1898Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1239195774, COSV54777128; called by muse, mutect2, varscan2
- CNTLN | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1196099221, COSV52090432; called by muse, mutect2, varscan2
- COL4A6 | c.4445G>A p.C1482Y | Missense Mutation (SNP) | VAF 79/135 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57873683; called by muse, mutect2, varscan2
- COL6A3 | c.3895G>C p.V1299L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV55101798; called by muse, mutect2, varscan2
- COLQ | c.677A>T p.H226L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV67525516; called by muse, mutect2, varscan2
- CPLX3 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV100547840, COSV59002976; called by muse, mutect2, varscan2
- CREB3L2 | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57798434; called by muse, mutect2, varscan2
- CSRNP1 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 50/55 reads (91%) | catalogued as rs1230748813, COSV56189389, COSV99826742; called by muse, mutect2, varscan2
- CSTF3 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV60611196, COSV60613360; called by muse, mutect2, varscan2
- CYP19A1 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV53061398; called by muse, mutect2, varscan2
- CYP2S1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.761); catalogued as COSV59506957; called by muse, mutect2, varscan2
- DDX19B | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 197/308 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as COSV55365223; called by muse, mutect2, varscan2
- DDX23 | c.1974C>G p.I658M | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV56400034; called by muse, mutect2, varscan2
- DDX3X | c.374G>C p.R125P (on ENST00000399959; = p.R126P on NM_001356.5) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV67864189; called by muse, mutect2, varscan2
- DDX54 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1417671344, COSV100013504; called by muse, mutect2
- DHTKD1 | c.2095C>G p.H699D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53805676; called by muse, mutect2, varscan2
- DHX35 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV52672816; called by muse, mutect2, varscan2
- DNM1 | c.790T>C p.S264P | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV57854758; called by muse, mutect2, varscan2
- DNMT3B | c.893A>T p.Y298F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52421586; called by muse, mutect2, varscan2
- DPRX | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); catalogued as COSV64949885; called by muse, mutect2, varscan2
- DRAM2 | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs1170401590, COSV54416189; called by muse, mutect2, varscan2
- DYRK1A | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs1429991264, COSV58296191; called by muse, mutect2, varscan2
- EGR4 | c.1650C>A p.F550L (on ENST00000545030; = p.F447L on NM_001965.4) | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1238804146, COSV101474253, COSV71532246; called by muse, mutect2, varscan2
- EGR4 | c.527C>T p.A176V (on ENST00000545030; = p.A73V on NM_001965.4) | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs751180263, COSV71531897; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1548G>C p.E516D | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57517439; called by muse, mutect2, varscan2
- ENPP2 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV50028322; called by muse, mutect2, varscan2
- ENTPD1 | c.411C>G p.L137= | Splice Region (SNP) | VAF 23/32 reads (72%) | catalogued as COSV64603510; called by muse, mutect2, varscan2
- EPB41L3 | c.2734G>T p.A912S | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV59463355; called by muse, mutect2, varscan2
- EPHB2 | c.647G>C p.S216T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV65864948; called by muse, mutect2, varscan2
- ERG | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/41 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.38); catalogued as COSV67366082; called by muse, mutect2, varscan2
- FAM124A | c.724C>G p.R242G (on ENST00000322475 / NM_001242312.2; = p.R278G on NM_145019.4) | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54476702, COSV54479003; called by muse, mutect2, varscan2
- FAM13B | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as COSV50370438; called by muse, mutect2, varscan2
- FAM151A | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV56365380; called by muse, mutect2, varscan2
- FAM83E | c.834C>G p.S278R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV52377832, COSV52377881; called by muse, mutect2, varscan2
- FAT3 | c.3547C>G p.L1183V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV53153747; called by muse, mutect2, varscan2
- FBLN1 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV53051833; called by muse, mutect2, varscan2
- FBXO11 | c.2556-1G>C p.X852_splice (on ENST00000403359 / NM_001190274.2; = p.X768_splice on NM_025133.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/129 reads (14%) | catalogued as COSV52284867; called by muse, mutect2, varscan2
- FICD | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as rs778841180, COSV57209667; called by muse, mutect2, varscan2
- FLNC | c.4940G>T p.G1647V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV57953098, COSV57961410; called by mutect2, varscan2
- FLVCR2 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.99); PolyPhen benign (0.03); catalogued as COSV53163845; called by muse, mutect2, varscan2
- GLT6D1 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65628212; called by muse, mutect2, varscan2
- GOLGA4 | c.5466A>C p.K1822N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV62712703; called by muse, mutect2, varscan2
- GRAMD1B | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1389438565, COSV59208793; called by muse, mutect2, varscan2
- GSS | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs144955088; called by muse, mutect2, varscan2
- GTF2IRD1 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56086435, COSV56089950; called by muse, varscan2
- GTF2IRD1 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1554345441, COSV56084708, COSV56087460; called by muse, mutect2, varscan2
- GYS1 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV54401296; called by muse, mutect2, varscan2
- HAO2 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV58041396; called by muse, mutect2, varscan2
- HAUS5 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99177696; called by muse, mutect2, varscan2
- HERC2 | c.11695G>C p.D3899H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs773927246, COSV55341526; called by mutect2, varscan2
- HHATL | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as COSV60042782; called by muse, mutect2, varscan2
- HLTF | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV59502617; called by muse, mutect2, varscan2
- HNF1A | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV57465537; called by muse, mutect2, varscan2
- IFI44 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV100877385, COSV66075336; called by muse, mutect2, varscan2
- IFIT5 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs575185602, COSV65655805; called by muse, mutect2, varscan2
- IFNA21 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.204); catalogued as COSV66518179, COSV66518646, COSV66518665; called by muse, mutect2, varscan2
- IFNLR1 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV59527247; called by muse, mutect2, varscan2
- ILDR1 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403349258, COSV56552331; called by muse, mutect2, varscan2
- INSIG2 | c.639C>G p.Y213* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99830356; called by muse, mutect2, varscan2
- INSYN2A | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV54752625; called by muse, mutect2, varscan2
- IPO7 | c.2852A>G p.D951G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV65686388; called by muse, mutect2, varscan2
- IRAK1 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100317717; called by muse, mutect2
- ITGA9 | c.2811C>A p.F937L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV53249171; called by muse, mutect2, varscan2
- ITPKA | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53028775; called by muse, mutect2, varscan2
- KATNIP | c.4084C>T p.L1362F | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs897423623, COSV55188289; called by muse, mutect2, varscan2
- KCNQ3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66477892; called by muse, mutect2, varscan2
- KDM1A | c.1577G>C p.R526T | Missense Mutation (SNP) | VAF 119/141 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63089383; called by muse, mutect2, varscan2
- KDM6A | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 59/139 reads (42%) | catalogued as COSV100937748; called by muse, mutect2, varscan2
- KIAA0930 | c.473T>A p.I158N (on ENST00000336156 / NM_001009880.2; = p.I163N on NM_015264.2) | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV52664651; called by muse, mutect2, varscan2
- KIF26A | c.3679C>G p.R1227G | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs201828613; called by muse, mutect2, varscan2
- KIF9 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV55522322; called by muse, mutect2, varscan2
- KRBA2 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58779447; called by muse, mutect2, varscan2
- LILRB5 | c.1625C>A p.A542D (on ENST00000449561 / NM_001081442.3; = p.A541D on NM_006840.5) | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1203224763, COSV60259999; called by muse, mutect2, varscan2
- LMO2 | c.167G>T p.S56I (on ENST00000395833 / NM_001142315.2; = p.S125I on NM_005574.4) | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57647040; called by muse, mutect2, varscan2
- LMTK2 | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV52001129; called by muse, mutect2, varscan2
- LRIG3 | c.2362C>G p.P788A | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs772436817, COSV57867745; called by muse, mutect2, varscan2
- LSM14B | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1365590837, COSV99443601; called by muse, mutect2
- LTN1 | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1359673925, COSV63734780; called by muse, mutect2, varscan2
- MAOA | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV58644636; called by muse, mutect2, varscan2
- MBOAT1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 80/102 reads (78%) | catalogued as rs567317695, COSV61127749; called by muse, mutect2, varscan2
- MCM4 | c.1561C>G p.Q521E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV50628901; called by muse, mutect2, varscan2
- MDN1 | c.7309G>C p.D2437H | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65527282; called by muse, mutect2, varscan2
- MED13 | c.3413C>T p.S1138L | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV67265894; called by muse, mutect2, varscan2
- MITD1 | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56806531, COSV56806843; called by muse, mutect2, varscan2
- MITF | c.801A>T p.Q267H (on ENST00000448226 / NM_006722.3; = p.Q161H on NM_000248.4) | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs567842156, COSV58834301; called by muse, mutect2, varscan2
- MITF | c.1460G>A p.G487D (on ENST00000448226 / NM_006722.3; = p.G387D on NM_000248.4) | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1200556656, COSV58834329; called by muse, mutect2, varscan2
- MRM3 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58680318; called by muse, mutect2, varscan2
- MRTFA | c.2990G>A p.G997D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV50654148; called by muse, mutect2, varscan2
- MTERF3 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99749448; called by muse, mutect2, varscan2
- MTMR4 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs61739434, COSV60202167; called by muse, mutect2, varscan2
- MUC16 | c.4910G>T p.G1637V | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV67482021; called by muse, mutect2, varscan2
- MUC4 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.955); catalogued as rs1303853210, COSV62175951; called by muse, mutect2, varscan2
- MVD | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99964697; called by muse, mutect2, varscan2
- MYBPC2 | c.2995G>T p.G999C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63098447; called by muse, mutect2, varscan2
- NDOR1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV61289423; called by muse, mutect2, varscan2
- NFIX | c.698C>G p.T233S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV62179340; called by muse, mutect2, varscan2
- NLRP12 | c.1645G>C p.A549P | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs761571455, COSV60746932, COSV60752024; called by muse, mutect2, varscan2
- NOS1 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | catalogued as COSV57613454; called by muse, mutect2, varscan2
- NOS1 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100499809; called by muse, mutect2, varscan2
- NPL | c.553T>G p.C185G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51126192; called by muse, mutect2, varscan2
- NPR2 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV61313573; called by muse, mutect2, varscan2
- NRP1 | c.2419G>C p.E807Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as COSV55173809; called by muse, mutect2, varscan2
- NTRK3 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV58115568, COSV58135680; called by muse, mutect2, varscan2
- NUDT13 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV61969657; called by muse, mutect2, varscan2
- OPA3 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780614894, COSV55607693; called by muse, mutect2, varscan2
- PALB2 | c.693A>T p.K231N | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs876658847, COSV55168664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARD6A | c.59G>C p.S20T | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV54669449; called by muse, mutect2, varscan2
- PARD6A | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV54669458; called by muse, mutect2, varscan2
- PARD6A | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54666715, COSV54669463; called by muse, mutect2, varscan2
- PARP9 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100830841; called by muse, mutect2, varscan2
- PCDHB14 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs781926933, COSV53390206; called by muse, mutect2, varscan2
- PCED1A | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62314070; called by muse, mutect2, varscan2
- PDE4DIP | c.4321C>G p.L1441V | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57711437, COSV57718198; called by muse, mutect2
- PHF3 | c.751C>A p.H251N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV50331159; called by muse, mutect2, varscan2
- PHGDH | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65571944; called by muse, mutect2, varscan2
- PLPPR4 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1171597884, COSV64567141; called by muse, mutect2, varscan2
- PLS3 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV56781080; called by muse, mutect2, varscan2
- PMP22 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1213064078, COSV56603039, COSV56603048; called by muse, mutect2, varscan2
- PNPLA8 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV57554043; called by muse, mutect2, varscan2
- POLDIP2 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs782668412, COSV50228744; called by muse, mutect2, varscan2
- POLR2B | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178799312, COSV58901560, COSV58902027; called by muse, mutect2, varscan2
- PPID | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56988743; called by mutect2, varscan2
- PPL | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs779295320, COSV52171017; called by muse, mutect2, varscan2
- PPP1R9A | c.2370G>C p.K790N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56904541; called by muse, mutect2
- PSMA6 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV54838689; called by muse, mutect2, varscan2
- PTP4A2 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59775094; called by muse, mutect2, varscan2
- PVR | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.716); catalogued as COSV51824236; called by muse, mutect2, varscan2
- RAI1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1567913839, COSV55396779; called by muse, mutect2, varscan2
- RBFOX1 | c.1168G>T p.G390* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV60990469; called by muse, mutect2, varscan2
- RIMKLA | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV68909920; called by muse, mutect2, varscan2
- ROCK2 | c.3919A>G p.K1307E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV59954102, COSV59962550; called by muse, mutect2, varscan2
- RRNAD1 | c.1024C>G p.R342G | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531073742, COSV63929322; called by muse, mutect2, varscan2
- RTL10 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.029); catalogued as rs745966542, COSV60736150; called by muse, varscan2
- SART3 | c.2843C>G p.A948G (on ENST00000228284; = p.A930G on NM_014706.4) | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV57209675; called by muse, mutect2, varscan2
- SCAF11 | c.837T>G p.H279Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1282413177, COSV101013989; called by muse, mutect2
- SCAI | c.1777G>A p.D593N (on ENST00000336505 / NM_001144877.3; = p.D616N on NM_173690.5) | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV60616101; called by muse, mutect2, varscan2
- SCUBE1 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV51814853; called by muse, mutect2, varscan2
- SECISBP2 | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV60529699; called by muse, mutect2, varscan2
- SETD5 | c.4087C>G p.Q1363E | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV100200964, COSV56715422; called by muse, mutect2, varscan2
- SETDB1 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.266); catalogued as COSV54989826; called by muse, mutect2, varscan2
- SLC16A6 | c.1425G>C p.K475N | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100517135; called by muse, mutect2
- SLC17A8 | c.1697G>C p.R566T | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV60125641; called by muse, mutect2, varscan2
- SLC22A7 | c.1205G>A p.R402H (on ENST00000372585 / NM_153320.2; = p.R400H on NM_006672.3) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.751); catalogued as rs1022105679, COSV51485086; called by muse, mutect2, varscan2
- SLC23A2 | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57777669; called by muse, mutect2, varscan2
- SLC24A4 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118603; called by muse, mutect2, varscan2
- SLC26A7 | c.779del p.P260Lfs*2 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as COSV52605955; called by mutect2, pindel, varscan2
- SLC39A7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1202409452, COSV63002249; called by muse, mutect2
- SLC4A1 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52262021; called by muse, mutect2, varscan2
- SLC4A3 | c.3020C>G p.T1007R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56096323; called by muse, mutect2
- SLIT1 | c.3637G>A p.A1213T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56595420; called by muse, mutect2, varscan2
- SLX4 | c.5302C>G p.Q1768E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53566978; called by muse, mutect2, varscan2
- SMURF2 | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52318238; called by muse, mutect2, varscan2
- SNX2 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1215129713, COSV65348799; called by muse, mutect2, varscan2
- SOWAHB | c.1226G>C p.S409T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV57554994; called by muse, mutect2, varscan2
- SPATA31E1 | c.2414C>G p.P805R | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1430407324, COSV57794035; called by muse, mutect2, varscan2
- SRL | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs373144625; called by muse, mutect2, varscan2
- ST6GAL1 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | PolyPhen benign (0); catalogued as COSV51473122; called by muse, mutect2, varscan2
- ST8SIA2 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 44/88 reads (50%) | PolyPhen probably damaging (0.995); catalogued as COSV51571757; called by muse, mutect2, varscan2
- STAB2 | c.4853A>G p.E1618G | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV66344061; called by muse, mutect2, varscan2
- SUSD5 | c.1655G>T p.S552I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs1324967354, COSV58879423; called by muse, mutect2, varscan2
- SYNE2 | c.11140G>C p.E3714Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV59962635; called by muse, mutect2, varscan2
- SYNPO2L | c.2624C>T p.A875V (on ENST00000394810 / NM_001114133.3; = p.A651V on NM_024875.5) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV65736793, COSV65738426; called by muse, mutect2, varscan2
- SZT2 | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV65172693; called by muse, mutect2, varscan2
- TBCD | c.1536C>T p.A512= | Splice Region (SNP) | VAF 7/57 reads (12%) | catalogued as rs759467452, COSV100832725, COSV62801224; called by muse, mutect2, varscan2
- TBL1X | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV54285673; called by muse, mutect2, varscan2
- TENM1 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64439168; called by muse, mutect2, varscan2
- TENM3 | c.3758A>T p.N1253I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV69315254; called by muse, mutect2, varscan2
- TENM4 | c.8200G>T p.V2734L | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV53654924; called by muse, mutect2, varscan2
- TEX14 | c.3989T>C p.L1330P (on ENST00000240361 / NM_001201457.2; = p.L1284P on NM_031272.5) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53623369; called by muse, mutect2, varscan2
- TG | c.7659T>A p.D2553E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV55088735; called by muse, mutect2, varscan2
- TGS1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1214538467, COSV99484919; called by muse, mutect2
- THBS1 | c.2681G>T p.C894F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52954552; called by muse, mutect2, varscan2
- THEMIS2 | c.1821G>T p.K607N (on ENST00000373921 / NM_001286115.1; = p.D250Y on NM_004848.3) | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs1199278222, COSV61078259; called by muse, mutect2, varscan2
- TIPARP | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV55813941; called by muse, mutect2, varscan2
- TNFSF10 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.274); catalogued as COSV53844086; called by muse, mutect2, varscan2
- TNIP1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59309140; called by muse, mutect2
- TOM1L2 | c.608C>T p.P203L (on ENST00000379504 / NM_001350333.2; = p.P153L on NM_001033551.3) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs745885112, COSV58888109; called by muse, mutect2, varscan2
- TOP1MT | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 33/174 reads (19%) | catalogued as rs752158768, COSV100239073; called by muse, mutect2, varscan2
- TPRN | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV58808606; called by muse, mutect2, varscan2
- TRAF3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749698005, COSV61026781; called by muse, mutect2, varscan2
- TRIO | c.5878G>C p.E1960Q | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as COSV60090704; called by muse, mutect2, varscan2
- TRMT10C | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59306530; called by muse, mutect2, varscan2
- TRPC1 | c.2344C>T p.R782W (on ENST00000476941 / NM_001251845.2; = p.R748W on NM_003304.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs572433240, COSV56428127; called by muse, mutect2, varscan2
- TRPV6 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs762853572, COSV63892983; called by muse, mutect2, varscan2
- TSHZ3 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53672115, COSV53678473; called by muse, mutect2, varscan2
- TSPAN14 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV55420355; called by muse, mutect2
- TTLL9 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.11); catalogued as COSV60595104; called by muse, mutect2, varscan2
- TTN | c.68048C>A p.P22683H (on ENST00000591111; = p.P15259H on NM_003319.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV100634245, COSV60241162; called by muse, mutect2, varscan2
- TTN | c.35714C>T p.P11905L (on ENST00000591111; = p.P4481L on NM_003319.4) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | PolyPhen probably damaging (0.994); catalogued as COSV60241198; called by muse, mutect2, varscan2
- TTN | c.32446G>C p.E10816Q (on ENST00000591111; = p.E9889Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/118 reads (53%) | PolyPhen benign (0.23); catalogued as rs976161757, COSV60241226; called by muse, mutect2, varscan2
- TUBGCP2 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV53307578; called by muse, mutect2, varscan2
- TUBGCP6 | c.3146G>A p.R1049Q | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs774109639, COSV50567496; called by muse, mutect2, varscan2
- TULP3 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 105/109 reads (96%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV68118467; called by muse, mutect2, varscan2
- TYK2 | c.980G>A p.W327* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as rs1384708218, COSV99313902; called by muse, mutect2, varscan2
- USF1 | c.603G>T p.R201S | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57039012; called by muse, mutect2
- USP34 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68404417; called by muse, mutect2, varscan2
- VPS13D | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1225910412, COSV62532928; called by muse, mutect2, varscan2
- VPS35L | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV51981816, COSV99219190; called by muse, mutect2, varscan2
- VRTN | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.142); catalogued as COSV99832060; called by muse, mutect2
- WNK1 | c.5312G>C p.G1771A (on ENST00000315939 / NM_018979.4; = p.G1524A on NM_014823.3) | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.817); catalogued as rs770566791, COSV60041699; called by muse, mutect2, varscan2
- WWTR1 | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV62292398; called by muse, mutect2, varscan2
- YTHDC2 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781198563, COSV50748821; called by muse, mutect2, varscan2
- ZFP37 | c.1871C>G p.S624* | Nonsense Mutation (SNP) | VAF 35/44 reads (80%) | catalogued as COSV100953114; called by muse, mutect2, varscan2
- ZG16B | c.602C>A p.S201* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV101206738; called by muse, mutect2, varscan2
- ZIK1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748130966, COSV56737071; called by muse, varscan2
- ZNF394 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58744015; called by muse, mutect2, varscan2
- ZNF407 | c.4091A>C p.K1364T | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV55263964; called by muse, mutect2, varscan2
- ZNF558 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 136/151 reads (90%) | catalogued as COSV100037760; called by muse, mutect2, varscan2
- ZNF804A | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV56462964, COSV56470311; called by muse, mutect2, varscan2
- ZSWIM3 | c.1490C>G p.T497S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54850044; called by muse, mutect2, varscan2
- ABCA13 | c.3501_3525del p.D1168Ifs*15 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel
- ALMS1 | c.7949_7983del p.S2650Ifs*13 | Frame Shift Del (DEL) | VAF 25/120 reads (21%) | called by mutect2, pindel
- CPSF3 | c.601_609+9del p.X201_splice | Splice Site (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- DNMT1 | c.2046_2069del p.S682_R689del | In Frame Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel
- DSC3 | c.355-33_368del p.X119_splice | Splice Site (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel
- FGF13 | c.527_529del p.E176del | In Frame Del (DEL) | VAF 30/121 reads (25%) | called by pindel, varscan2
- GPR156 | c.601-10_613del p.X201_splice | Splice Site (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel
- IGLV5-45 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- KNTC1 | c.1130+3_1130+6del p.X377_splice | Splice Site (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- LRRC37B | c.1452C>A p.S484R | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by mutect2, varscan2
- MALT1 | c.578_620del p.N193Mfs*32 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel
- NEUROD1 | c.1018del p.S340Hfs*7 | Frame Shift Del (DEL) | VAF 50/113 reads (44%) | called by mutect2, pindel, varscan2
- OR2L8 | chr1:247948848 del GGAATGCTCCAT | Missense Mutation (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- REL | c.705_741del p.V236Hfs*10 | Frame Shift Del (DEL) | VAF 52/169 reads (31%) | called by mutect2, pindel
- SEC61A1 | c.250_251dup p.V85Lfs*7 | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.1177_1183del p.A393Ifs*16 | Frame Shift Del (DEL) | VAF 45/50 reads (90%) | called by mutect2, pindel, varscan2
- TADA2A | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TERF2 | c.693_693+3delinsT p.X231_splice | Splice Site (DEL) | VAF 40/73 reads (55%) | called by pindel, varscan2*
- WASHC2C | c.3793G>T p.D1265Y (on ENST00000336378; = p.D1244Y on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA1 | c.246C>T p.F82= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV66059450; called by muse, mutect2, varscan2
- ACSM2A | c.708G>A p.S236= (on ENST00000219054; = p.S157= on NM_001308169.2) | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs780104239, COSV99524731; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1752G>T p.V584= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs747769897, COSV54460940; called by muse, mutect2, varscan2
- AGFG2 | c.603C>T p.H201= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs200992157, COSV53546521; called by muse, mutect2, varscan2
- AKAP13 | c.657A>G p.L219= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs751735705, COSV63465693; called by muse, mutect2, varscan2
- APEX2 | c.1068G>A p.T356= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs774201190, COSV58192571, COSV58193180; called by muse, mutect2, varscan2
- BRCA1 | c.4800G>A p.L1600= | Silent (SNP) | VAF 96/106 reads (91%) | catalogued as COSV58796135; called by muse, varscan2
- C3AR1 | c.870C>G p.L290= | Silent (SNP) | VAF 48/55 reads (87%) | catalogued as rs776792906, COSV50821796; called by muse, mutect2, varscan2
- C5orf15 | c.381G>A p.E127= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV51548839; called by muse, mutect2, varscan2
- C9orf131 | c.453G>T p.G151= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as COSV56613015; called by muse, mutect2, varscan2
- CACUL1 | c.171G>A p.L57= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100432333; called by muse, mutect2
- CCIN | c.786G>A p.Q262= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs989895447, COSV58725267; called by muse, mutect2, varscan2
- CD3G | c.435G>A p.S145= | Silent (SNP) | VAF 73/83 reads (88%) | catalogued as COSV52675737; called by muse, mutect2, varscan2
- CEP135 | c.3069T>A p.L1023= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57261941; called by muse, mutect2, varscan2
- CEP170 | c.2403A>G p.R801= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV60512382; called by muse, mutect2, varscan2
- COA5 | c.63G>A p.L21= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs200892190, COSV100158657, COSV60831387; called by muse, varscan2
- CSPP1 | c.57A>G p.L19= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1382795214, COSV51589808; called by muse, mutect2, varscan2
- DERL2 | c.345G>A p.V115= | Silent (SNP) | VAF 54/60 reads (90%) | catalogued as COSV50147736; called by muse, mutect2, varscan2
- DLG4 | c.2100C>A p.I700= (on ENST00000399506 / NM_001321075.3; = p.I743= on NM_001365.4) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV57239190; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.423G>A p.V141= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs752975974, COSV50052558; called by muse, mutect2, varscan2
- EFCAB1 | c.180A>G p.T60= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV50619315; called by muse, mutect2, varscan2
- EMILIN3 | c.1960C>T p.L654= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60037976; called by muse, mutect2, varscan2
- EMILIN3 | c.577C>T p.L193= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV60036965, COSV60037985; called by muse, mutect2, varscan2
- EPB41L2 | c.186G>A p.Q62= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV61357790; called by muse, mutect2, varscan2
- ERBB3 | c.2679T>C p.D893= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV57259692; called by muse, mutect2, varscan2
- ESPN | c.1929C>T p.F643= | Silent (SNP) | VAF 23/25 reads (92%) | catalogued as COSV64704280; called by muse, mutect2, varscan2
- FAM90A1 | c.924G>C p.P308= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV100274118; called by muse, mutect2, varscan2
- FAT4 | c.1587C>T p.S529= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs770456067, COSV67885457; called by muse, mutect2, varscan2
- FCGRT | c.129G>A p.G43= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV55528674, COSV55528776, COSV55530594; called by muse, mutect2, varscan2
- FER1L6 | c.4587C>T p.L1529= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV67551799; called by muse, mutect2, varscan2
- FRMPD1 | c.1935G>A p.E645= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs745646059, COSV66701845; called by muse, mutect2, varscan2
- GLDC | c.729C>T p.L243= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs1372919732, CD1510050, COSV58683387; called by muse, mutect2, varscan2
- GNB2 | c.759C>T p.F253= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs779424974, COSV51939756, COSV51940484; called by muse, mutect2, varscan2
- GTF2IRD1 | c.342C>T p.L114= | Silent (SNP) | VAF 36/38 reads (95%) | catalogued as COSV56089938; called by muse, varscan2
- GUCY2C | c.357C>G p.L119= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV53793866; called by muse, mutect2, varscan2
- HTT | c.4059C>A p.G1353= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV61866681; called by muse, mutect2, varscan2
- IFNLR1 | c.1434C>T p.S478= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1361484103, COSV59527241; called by muse, mutect2, varscan2
- IGF2BP2 | c.1446G>A p.P482= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1205756383, COSV60489648; called by muse, mutect2, varscan2
- JHY | c.1887A>G p.Q629= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as rs1467417051, COSV57078565; called by muse, mutect2, varscan2
- L3MBTL1 | c.2217C>G p.A739= (on ENST00000418998 / NM_001377303.1; = p.A649= on NM_015478.7) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV64229343; called by muse, mutect2, varscan2
- LACTB2 | c.372G>C p.L124= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV52569002; called by muse, mutect2, varscan2
- LENG8 | c.657A>G p.Q219= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs780656929, COSV100457027; called by muse, mutect2, varscan2
- LGI3 | c.486G>C p.L162= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs143382116, COSV60444183; called by muse, mutect2, varscan2
- LRRC66 | c.393T>C p.P131= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV58635816; called by muse, mutect2, varscan2
- MGAM | c.5109T>C p.P1703= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV72075279; called by muse, mutect2, varscan2
- MTMR4 | c.417G>C p.L139= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV60202180; called by muse, mutect2, varscan2
- MTREX | c.474A>G p.L158= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs1485090211, COSV57928776; called by muse, mutect2, varscan2
- MUC16 | c.39462C>T p.S13154= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1396203877, COSV66690904; called by muse, mutect2, varscan2
- NBPF11 | c.1857C>G p.L619= | Silent (SNP) | VAF 119/149 reads (80%) | catalogued as rs1346524513; called by muse, mutect2, varscan2
- NDOR1 | c.1614G>A p.R538= (on ENST00000371521 / NM_001144026.3; = p.R522= on NM_014434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as COSV61289435; called by muse, mutect2, varscan2
- NDST4 | c.1662G>A p.V554= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV52130771; called by muse, mutect2, varscan2
- OASL | c.132G>C p.L44= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV57479861; called by muse, mutect2, varscan2
- OR2A12 | c.687T>C p.S229= | Silent (SNP) | VAF 60/258 reads (23%) | catalogued as COSV68821803; called by muse, mutect2, varscan2
- POU2F2 | c.561C>T p.C187= (on ENST00000526816 / NM_001207025.3; = p.C171= on NM_002698.5) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100657141; called by muse, mutect2
- PRDM15 | c.1968G>T p.A656= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV54157156; called by muse, mutect2, varscan2
- R3HCC1L | c.786A>T p.G262= | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as rs1279143201, COSV54404105; called by muse, mutect2, varscan2
- RAB22A | c.120A>T p.A40= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV54833069; called by muse, mutect2, varscan2
- RGS8 | c.318T>C p.H106= (on ENST00000367556 / NM_001369564.2; = p.H124= on NM_033345.3) | Silent (SNP) | VAF 52/218 reads (24%) | catalogued as rs780836447, COSV51118460; called by muse, mutect2, varscan2
- RGS9 | c.1179C>A p.T393= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99286981; called by muse, mutect2
- SEL1L3 | c.1509G>T p.L503= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as rs1356053177, COSV99339091; called by muse, mutect2, varscan2
- SETDB1 | c.2955G>A p.L985= | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as COSV54989799, COSV99645345; called by muse, mutect2, varscan2
- SH2D5 | c.717C>A p.A239= (on ENST00000444387 / NM_001103161.2; = p.A155= on NM_001103160.2) | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV66707276; called by muse, mutect2, varscan2
- SH3PXD2A | c.3087G>A p.K1029= (on ENST00000369774 / NM_001365079.1; = p.K1001= on NM_014631.2) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1167816888, COSV60119242; called by muse, mutect2
- SMO | c.1110C>T p.V370= | Silent (SNP) | VAF 51/88 reads (58%) | catalogued as rs779576969, COSV50836649; called by muse, mutect2, varscan2
- SOX7 | c.246G>A p.S82= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs769113063, COSV58730973; called by muse, mutect2, varscan2
- SRCAP | c.5931C>T p.I1977= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV52678222; called by muse, mutect2, varscan2
- STRADB | c.765G>T p.G255= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV52045204; called by muse, mutect2, varscan2
- SUGP1 | c.1866C>T p.F622= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs1165755979, COSV55923160; called by muse, mutect2, varscan2
- SUGP2 | c.960T>C p.D320= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV58262901; called by muse, mutect2, varscan2
- TEAD4 | c.165C>A p.L55= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as COSV63281985; called by muse, mutect2, varscan2
- THAP9 | c.2583G>A p.E861= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV56357271; called by muse, mutect2, varscan2
- TMEM203 | c.177C>T p.L59= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV58808618; called by muse, mutect2, varscan2
- TPRN | c.1899C>T p.F633= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs530636499, COSV58808594; called by muse, mutect2, varscan2
- TTBK2 | c.2286T>C p.H762= | Silent (SNP) | VAF 131/196 reads (67%) | catalogued as COSV51171153; called by muse, mutect2, varscan2
- UBE2L6 | c.165C>T p.I55= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV54703609; called by muse, mutect2, varscan2
- UBR5 | c.2157C>G p.V719= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV55295626; called by muse, mutect2, varscan2
- UNC79 | c.5559C>G p.L1853= (on ENST00000393151 / NM_001346218.2; = p.L1676= on NM_020818.5) | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV56402541; called by muse, mutect2, varscan2
- VIRMA | c.3345C>G p.L1115= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV52589147; called by muse, mutect2, varscan2
- VPS54 | c.1182G>A p.K394= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV55443558; called by muse, mutect2, varscan2
- ZBTB17 | c.1422C>T p.L474= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV65271156; called by muse, mutect2, varscan2
- ZFYVE26 | c.2565G>A p.T855= | Silent (SNP) | VAF 57/70 reads (81%) | catalogued as rs145738942; called by muse, mutect2, varscan2
- ZNF804A | c.2184A>G p.K728= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV56462973; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845579 C>T | 5'Flank (SNP) | VAF 21/23 reads (91%) | called by muse, mutect2, varscan2
- COMT | c.-185C>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs768636039, COSV100538487; called by muse, varscan2
- DST | c.4296+4727G>C | Intron (SNP) | VAF 29/128 reads (23%) | catalogued as COSV55031554; called by muse, mutect2, varscan2
- LRRC71 | c.1563+13C>G | Intron (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100168095; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4616G>A | Intron (SNP) | VAF 66/149 reads (44%) | catalogued as COSV52902688; called by muse, mutect2, varscan2
- OR4K1 | c.-1C>T | 5'UTR (SNP) | VAF 60/170 reads (35%) | catalogued as COSV99578511; called by muse, mutect2, varscan2
- SNORD116-15 | n.8T>G | RNA (SNP) | VAF 39/271 reads (14%) | called by muse, mutect2, varscan2
- SPATA8 | n.885T>C | RNA (SNP) | VAF 29/65 reads (45%) | catalogued as COSV60704029, COSV60705352; called by muse, mutect2, varscan2
- TTN | c.10360+5046G>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as COSV60241234; called by muse, mutect2, varscan2
